Somatic mutation profile of tumor specimen TCGA-12-0773-01A (aliquot TCGA-12-0773-01A-01W-0348-08) from TCGA case TCGA-12-0773, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 24.2 years (8,849 days).
Specimen TCGA-12-0773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9021a1b-0383-424f-bb7d-07ca4e4cdc00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0773-10A (Blood Derived Normal), aliquot TCGA-12-0773-10A-01W-0348-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22c8a8fd-ea19-4021-abd0-892391e3c70d

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 14, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 40/77 reads (52%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV64733062; called by muse, mutect2, varscan2
- TP53 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 230/275 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTL6B | c.695dup p.N233Kfs*17 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs779550102; called by mutect2, varscan2
- ALPK2 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 252/598 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as rs202105506; called by muse, mutect2, varscan2
- CCDC59 | c.393C>A p.D131E | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99810724; called by muse, mutect2, varscan2
- COLEC11 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.84); catalogued as rs754115098, COSV52598860; called by muse, mutect2, varscan2
- DNAH9 | c.6290T>C p.L2097P | Missense Mutation (SNP) | VAF 113/342 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963924338, COSV99306637; called by muse, mutect2, varscan2
- DSCAML1 | c.4942G>A p.D1648N (on ENST00000321322; = p.D1588N on NM_020693.4) | Missense Mutation (SNP) | VAF 101/439 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV58382318; called by muse, mutect2, varscan2
- GALNT5 | c.2419A>T p.I807F | Missense Mutation (SNP) | VAF 195/388 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV99375359; called by muse, mutect2, varscan2
- IGSF9 | c.1480C>T p.R494* (on ENST00000368094 / NM_001135050.2; = p.R478* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 67/212 reads (32%) | catalogued as rs1232969166, COSV100829642; called by muse, mutect2, varscan2
- IL2RB | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53427773; called by muse, mutect2, varscan2
- ITGA10 | c.1205G>T p.W402L | Missense Mutation (SNP) | VAF 32/680 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV100994969, COSV65195958; called by muse, mutect2
- ITPR1 | c.1126C>T p.R376C (on ENST00000354582; = p.R361C on NM_002222.7) | Missense Mutation (SNP) | VAF 154/465 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs748464709, COSV56992458; called by muse, mutect2, varscan2
- LAMA3 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 42/528 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100557114; called by muse, mutect2
- MAP3K3 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | catalogued as COSV62281682; called by muse, mutect2, varscan2
- PCDH12 | c.2052dup p.Q686Tfs*102 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | catalogued as rs748127746; called by mutect2, varscan2
- PLCG2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 228/456 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs775728338, COSV63870294, COSV63875704; called by muse, mutect2, varscan2
- RFX6 | c.1374G>T p.K458N | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV100263918; called by muse, mutect2, varscan2
- STX2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV99893029; called by muse, mutect2, varscan2
- TTN | c.6767C>T p.T2256M (on ENST00000591111; = p.T2210M on NM_003319.4) | Missense Mutation (SNP) | VAF 38/528 reads (7%) | PolyPhen probably damaging (0.988); catalogued as rs780758720, COSV59868854; called by muse, mutect2
- UBL5 | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100694862; called by muse, mutect2
- USP9Y | c.4904C>T p.T1635I | Missense Mutation (SNP) | VAF 278/312 reads (89%) | SIFT tolerated (0.17); PolyPhen benign (0.144); catalogued as COSV100168414; called by muse, mutect2, varscan2
- WEE1 | c.1169A>T p.E390V | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV100219771; called by muse, mutect2, varscan2
- ZNF335 | c.1760A>G p.E587G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100533174; called by muse, mutect2, varscan2
- ZNF462 | c.670G>C p.V224L | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as COSV99472513; called by muse, mutect2
- ZNF468 | c.403C>G p.R135G | Missense Mutation (SNP) | VAF 81/1260 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99700665; called by muse, mutect2
- ATRX | c.3120del p.D1041Mfs*9 | Frame Shift Del (DEL) | VAF 174/279 reads (62%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PLEKHG1 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- ZMIZ1 | c.56_57del p.K19Tfs*51 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, varscan2
- ACBD3 | c.732G>A p.Q244= | Silent (SNP) | VAF 56/307 reads (18%) | catalogued as COSV100831065; called by muse, mutect2, varscan2
- ALPK3 | c.1605C>T p.T535= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99361349; called by muse, mutect2, varscan2
- AOX1 | c.1395C>T p.G465= | Silent (SNP) | VAF 314/776 reads (40%) | catalogued as rs774911099, COSV101021707; called by muse, mutect2, varscan2
- CNTNAP1 | c.2286G>A p.T762= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs941710540, COSV99226672; called by muse, mutect2, varscan2
- COL18A1 | c.1611C>T p.G537= (on ENST00000359759 / NM_130444.3; = p.G302= on NM_030582.4) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs757344530, COSV100700779; called by muse, varscan2
- CRYBG3 | c.6654G>A p.S2218= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as rs753867444, COSV99477162; called by muse, mutect2, varscan2
- CSRNP1 | c.1596C>T p.I532= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs372252051, COSV99826952; called by muse, varscan2
- DPYSL3 | c.762G>A p.K254= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as COSV58330832; called by muse, mutect2
- HCK | c.714G>A p.S238= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs147876395; called by muse, mutect2, varscan2
- MAST1 | c.1764C>T p.F588= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1018835734, COSV52255526; called by muse, mutect2, varscan2
- MLPH | c.483C>T p.D161= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99222396; called by muse, mutect2, varscan2
- PRAMEF14 | c.573G>A p.P191= | Silent (SNP) | VAF 42/789 reads (5%) | catalogued as rs1379898711; called by muse, mutect2
- SIRPD | c.537C>T p.F179= | Silent (SNP) | VAF 62/177 reads (35%) | catalogued as rs758873532, COSV67547225; called by muse, mutect2, varscan2
- TNKS | c.912C>T p.H304= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as rs761562375, COSV60063727; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499073 T>A | 5'Flank (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- C9orf129 | n.599C>T | RNA (SNP) | VAF 54/120 reads (45%) | catalogued as COSV100962429; called by muse, mutect2, varscan2
